Gene-level copy-number profile of tumor specimen TCGA-HV-A5A3-01A from TCGA case TCGA-HV-A5A3, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 50.6 years (18,475 days).
Specimen TCGA-HV-A5A3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.89d82427-76a4-4143-8626-3265562d78ad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HV-A5A3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e8402c41-05a9-4704-9e55-55d48e414494

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 11,402; copy number 2: 36,577; copy number 3: 11,366; copy number 4: 13; copy number 5: 326; copy number 6: 5; copy number 7: 6; copy number 18: 68.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HV-A5A3-01A-11D-A26H-01): tumor purity 0.62, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–488,512, 16 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2.
- chr9:21,321,300–22,214,672, 35 genes: IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 405 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:63,719,980–65,707,226, 1 gene, copy number 6 (within-gene range 1–6): EYS.
- chr6:64,377,795–64,733,837, 3 genes, copy number 6: AL357375.1, HNRNPDP2, AL355357.1.
- chr8:78,148,101–78,956,082, 12 genes, copy number 5 (within-gene range 3–5): AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605.
- chr8:87,540,835–87,755,718, 1 gene, copy number 5 (within-gene range 3–5): AF121898.1.
- chr8:87,598,462–88,019,113, 5 genes, copy number 5: IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1.
- chr8:107,160,354–133,134,903, 299 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:133,046,481–133,057,767, 2 genes, copy number 5: MIR7848, PTCSC1.
- chr10:17,577,362–17,716,824, 6 genes, copy number 7 (within-gene range 2–7): PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1.
- chr12:30,086,342–30,321,617, 7 genes, copy number 5: AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1.
- chr12:67,929,235–70,637,440, 68 genes, copy number 18 (within-gene range 6–18) (broad region; genes not listed).
- chr12:70,671,918–70,672,856, 1 gene, copy number 6: FAHD2P1.

Autosomal genes at a single copy (total copy number 1): 8,981. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
